CCDI case PBCMLB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Renal pelvis.
https://portal.gdc.cancer.gov/cases/d7f5c755-9876-4d6c-9af3-2a43f714f873

Demographics
Sex at birth: female.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Renal pelvis; Age at diagnosis: 11.8 years (4,292 days).

Biospecimens (2 samples)
- Sample 0DVVL0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVVMB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
